Gene-level copy-number profile of tumor specimen ALCH-B01Y-TTP1-A from ALCHEMIST case ALCH-B01Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,894 days).
Specimen ALCH-B01Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3091261-b3d7-4397-a0fa-ffaf95ab86f9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/83b46a62-3c2c-448e-ad8d-f3c5493674cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,499; copy number 2: 51,336; copy number 3: 3,050; copy number 4: 16; copy number 6: 1; copy number 7: 1; copy number 8: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,508,537–2,526,597, 1 gene: PANK4.
- chr8:94,594,411–94,594,601, 1 gene: AC023632.4.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr5:135,802,985–135,803,075, 1 gene, copy number 8: MIR5692C1.
- chr13:112,313,467–112,321,758, 1 gene, copy number 11: LINC01043.
- chr16:32,600,299–32,615,639, 1 gene, copy number 6: AC137800.1.

Autosomal genes at a single copy (total copy number 1): 2,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
